Somatic mutation profile of tumor specimen TCGA-3U-A98I-01A (aliquot TCGA-3U-A98I-01A-11D-A39R-32) from TCGA case TCGA-3U-A98I, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 68.7 years (25,108 days).
Specimen TCGA-3U-A98I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f93a7e3-608b-4a29-b1db-94f75cb8d393.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3U-A98I-10A (Blood Derived Normal), aliquot TCGA-3U-A98I-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24997ba0-afd4-48f1-afbc-fd51c4b5c1f9

The open-access MAF lists 42 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APBB2 | c.955C>T p.R319W (on ENST00000295974 / NM_001166050.2; = p.R320W on NM_004307.2) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs538682911, COSV55954670; called by muse, mutect2, varscan2
- COL16A1 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1478950529; called by muse, mutect2, varscan2
- DOCK2 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 28/144 reads (19%) | catalogued as COSV56946991, COSV56976948; called by muse, mutect2, varscan2
- GSTM5 | c.36G>C p.G12= | Splice Region (SNP) | VAF 42/169 reads (25%) | catalogued as COSV99859310; called by muse, mutect2, varscan2
- IL1RAPL2 | c.980C>A p.A327E | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.587); catalogued as COSV61161110, COSV61173588; called by muse, mutect2, varscan2
- LRRIQ4 | c.443G>C p.G148A | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61620505; called by muse, mutect2, varscan2
- SCARA5 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1333456933; called by muse, mutect2, varscan2
- SCRIB | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1377528066; called by muse, mutect2, varscan2
- SDC2 | c.593del p.E198Gfs*9 | Frame Shift Del (DEL) | VAF 17/122 reads (14%) | catalogued as COSV56225583; called by mutect2, pindel, varscan2
- TULP4 | c.2281G>A p.V761M | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs369570435; called by muse, mutect2, varscan2
- USH2A | c.8342C>A p.T2781N | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as CM135887; called by muse, mutect2, varscan2
- ZFHX4 | c.9331G>A p.G3111R | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775472372, COSV50502233, COSV50619821, COSV99268389; called by muse, mutect2, varscan2
- B4GALNT3 | c.1356G>T p.M452I | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAZ2A | c.1923C>G p.I641M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, mutect2
- CEACAM1 | c.1385A>T p.D462V | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DLEC1 | c.3026G>A p.G1009E | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH17 | c.11919C>G p.S3973R | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- EP400 | c.7834C>T p.Q2612* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- FAM110D | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- FAM189B | c.819C>G p.D273E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- GRM7 | c.1475A>T p.Y492F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- IFNAR1 | c.1575_1611del p.K525Nfs*25 | Frame Shift Del (DEL) | VAF 15/119 reads (13%) | called by mutect2, pindel
- NEDD4L | c.1954_1963del p.F652Rfs*73 (on ENST00000400345 / NM_001144967.3; = p.F632Rfs*73 on NM_015277.6) | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- OCA2 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PPIL3 | c.425G>C p.R142P (on ENST00000392283 / NM_130906.3; = p.R146P on NM_032472.4) | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RETREG2 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- RTN3 | c.373C>G p.L125V (on ENST00000377819 / NM_001265589.2; = p.L106V on NM_201428.3) | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC34A3 | c.515C>G p.T172S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SNX16 | c.911A>T p.D304V | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TRPM4 | c.638G>A p.W213* | Nonsense Mutation (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.3641G>A p.C1214Y | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ZFP90 | c.1065A>T p.Q355H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ZNF804A | c.1577T>A p.L526H | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C2CD4A | c.723C>T p.R241= | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- FERMT3 | c.867G>A p.E289= | Silent (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- GPRIN2 | c.1284G>A p.L428= | Silent (SNP) | VAF 21/174 reads (12%) | catalogued as rs782757842; called by muse, mutect2, varscan2
- HELZ2 | c.858C>G p.G286= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- MECOM | c.105A>G p.E35= (on ENST00000468789 / NM_001105078.4; = p.E223= on NM_004991.4) | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- PRLR | c.1800C>T p.S600= | Silent (SNP) | VAF 28/131 reads (21%) | called by muse, mutect2, varscan2
- SPTBN1 | c.2880C>T p.Y960= | Silent (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- ZFP1 | c.435G>A p.K145= | Silent (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.693C>T p.H231= | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
